Gene-level copy-number profile of tumor specimen TCGA-EY-A54A-01A from TCGA case TCGA-EY-A54A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 68.0 years (24,822 days).
Specimen TCGA-EY-A54A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.2387f2b0-3e8d-4512-bdb5-30c9fc0c5c3b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A54A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a294f398-2377-4f10-abf3-757a683082d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 11,721; copy number 2: 43,799; copy number 3: 3,875; copy number 4: 393; copy number 5: 13; copy number 6: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A54A-01A-11D-A27O-01): tumor purity 0.79, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,858,659–169,038,416, 5 genes, copy number 6: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:172,828,736–172,831,229, 2 genes, copy number 6: ATP5MC1P4, AC108667.1.
- chr11:102,576,832–102,625,332, 1 gene, copy number 6 (within-gene range 3–6): MMP20.
- chr19:29,775,504–30,085,893, 13 genes, copy number 5: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.

Autosomal genes at a single copy (total copy number 1): 9,304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
